Somatic mutation profile of tumor specimen TCGA-06-0166-01A (aliquot TCGA-06-0166-01A-01D-1491-08) from TCGA case TCGA-06-0166, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 51.8 years (18,902 days).
Specimen TCGA-06-0166-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 16f6070a-09f2-41e7-bbc6-5afc01d47148.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0166-10A (Blood Derived Normal), aliquot TCGA-06-0166-10A-01D-1491-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/26511721-713f-4f7d-bcf2-0045a2d6f5a2

The open-access MAF lists 43 somatic variants for this specimen: 38 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Nonsense Mutation 4, Silent 3, In Frame Del 2, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BCOR | c.2428C>T p.R810* | Nonsense Mutation (SNP) | VAF 75/143 reads (52%) | catalogued as rs1555918056, CM095797, COSV60703357; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.29_49del p.L10_M16del | In Frame Del (DEL) | VAF 18/118 reads (15%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- ADGRL2 | c.3714G>C p.K1238N (on ENST00000370717 / NM_001366005.1; = p.K1182N on NM_012302.4) | Missense Mutation (SNP) | VAF 35/199 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs372665040, COSV54679889, COSV54686375; called by muse, mutect2, varscan2
- ASAP1 | c.2245G>C p.D749H | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.879); catalogued as COSV63052910; called by muse, mutect2
- ATF7IP2 | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.043); catalogued as rs773088201, COSV61094748; called by muse, mutect2, varscan2
- C10orf71 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.264); catalogued as COSV60510773; called by muse, mutect2, varscan2
- CDKL1 | c.56T>C p.V19A | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV53581663; called by muse, mutect2, varscan2
- DYNC1I1 | c.397C>T p.L133F | Missense Mutation (SNP) | VAF 175/725 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.943); catalogued as COSV61467635; called by muse, mutect2, varscan2
- DYNC2LI1 | c.628G>A p.A210T | Missense Mutation (SNP) | VAF 24/129 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.567); catalogued as COSV53184817; called by muse, mutect2, varscan2
- FCHSD1 | c.299G>A p.R100Q | Missense Mutation (SNP) | VAF 45/199 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as rs762942642, COSV53353183; called by muse, mutect2, varscan2
- FPR3 | c.920G>A p.R307H | Missense Mutation (SNP) | VAF 76/299 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs746950422, COSV59328604; called by muse, mutect2, varscan2
- FRMD5 | c.778G>A p.V260I | Missense Mutation (SNP) | VAF 13/191 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.146); catalogued as rs373951833, COSV68720935; called by muse, mutect2
- FTMT | c.316G>A p.V106M | Missense Mutation (SNP) | VAF 40/113 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs1178598495, COSV58420228, COSV58420991; called by muse, mutect2, varscan2
- GCNT3 | c.1264C>T p.Q422* | Nonsense Mutation (SNP) | VAF 128/382 reads (34%) | catalogued as COSV68532380; called by muse, mutect2, varscan2
- GMPR | c.565C>T p.R189C | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs763187569, COSV52474616; called by muse, mutect2
- HERC2 | c.6184T>C p.F2062L | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (0.51); PolyPhen benign (0.19); catalogued as COSV55341275; called by muse, mutect2, varscan2
- ILF3 | c.2398G>A p.D800N | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs755277787, COSV51555911; called by muse, mutect2, varscan2
- KNDC1 | c.2302A>C p.N768H | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.095); catalogued as COSV58843792; called by muse, varscan2
- LDLR | c.2174C>A p.S725Y | Missense Mutation (SNP) | VAF 71/183 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.251); catalogued as COSV52945089; called by muse, mutect2, varscan2
- LIMCH1 | c.1810G>A p.E604K | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.075); catalogued as COSV58292546; called by muse, mutect2, varscan2
- MECOM | c.265G>T p.G89W | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72111036; called by muse, mutect2
- MPP3 | c.730G>A p.A244T | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.971); catalogued as rs1226363264, COSV68198929; called by muse, mutect2, varscan2
- MYH1 | c.1250G>T p.G417V | Missense Mutation (SNP) | VAF 44/588 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56854729; called by muse, mutect2
- MYOD1 | c.523G>T p.A175S | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as rs143600911, COSV104375903; called by mutect2, varscan2
- NUP210 | c.3545G>A p.G1182D | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.935); catalogued as rs1454165779, COSV54411670; called by muse, mutect2
- PCLO | c.4014A>T p.K1338N | Missense Mutation (SNP) | VAF 44/154 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV61655164; called by muse, mutect2, varscan2
- PEX19 | c.62T>C p.L21P | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54107604; called by muse, mutect2, varscan2
- PTEN | c.500C>G p.T167S | Missense Mutation (SNP) | VAF 62/191 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as CM124578, COSV100910397, COSV64291531, COSV64303272; called by muse, mutect2, varscan2
- RASGRF1 | c.1289C>T p.T430M | Missense Mutation (SNP) | VAF 44/275 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769371347, COSV69180503; called by muse, mutect2, varscan2
- SLTM | c.1391C>T p.P464L | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.325); catalogued as COSV51056376; called by muse, mutect2, varscan2
- SPIRE1 | c.979G>T p.G327C | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59160676; called by muse, mutect2, varscan2
- TMEM132D | c.2857G>T p.E953* | Nonsense Mutation (SNP) | VAF 24/197 reads (12%) | catalogued as COSV67159738, COSV67160626; called by muse, mutect2, varscan2
- XCR1 | c.97G>A p.A33T | Missense Mutation (SNP) | VAF 36/166 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs140218706, COSV58569310; called by muse, mutect2, varscan2
- ZNF180 | c.1024C>T p.Q342* | Nonsense Mutation (SNP) | VAF 71/212 reads (33%) | catalogued as COSV55423124; called by muse, mutect2, varscan2
- ZNF618 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.041); catalogued as rs756981948, COSV55923524; called by muse, mutect2, varscan2
- ZRANB3 | c.3119T>C p.L1040P | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51510980; called by muse, mutect2, varscan2
- CCN3 | c.120_131del p.G41_P44del | In Frame Del (DEL) | VAF 6/21 reads (29%) | called by mutect2, pindel, varscan2
- MYO19 | c.1174G>A p.V392I | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ABCC1 | c.3603G>A p.V1201= | Silent (SNP) | VAF 32/124 reads (26%) | catalogued as COSV60691205; called by muse, mutect2, varscan2
- CLEC3A | c.462C>T p.N154= (on ENST00000651443; = p.N145= on NM_005752.6) | Silent (SNP) | VAF 65/211 reads (31%) | catalogued as rs757636173, COSV55222892; called by muse, mutect2, varscan2
- MMP24 | c.822C>T p.N274= | Silent (SNP) | VAF 7/20 reads (35%) | catalogued as rs201850633, COSV55772313; called by muse, mutect2
- AC024940.1 | n.3851C>T | RNA (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2, varscan2
- DCAF13 | chr8:103415109 ins G | 5'Flank (INS) | VAF 21/107 reads (20%) | called by mutect2, pindel, varscan2
